HCMI case HCM-CSHL-0725-C02 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Squamous Cell Neoplasms; Primary site: Other and unspecified parts of mouth. Index date (day 0 for every day count below): sample procurement.
https://portal.gdc.cancer.gov/cases/9bf63d26-2156-4556-a56e-7c49148441ce

Demographics
Sex at birth: female; Days to birth: -19,345 days (53.0 years before the index date); Year of birth: 1965; Vital status: Alive.

Diagnoses (1)
1. Squamous cell carcinoma, NOS: ICD-O-3 morphology code: 8070/3; ICD-10 code: C02.9; Tissue or organ of origin: Mouth, NOS; Site of resection or biopsy: Tongue, NOS; Laterality: Right; Classification of tumor: primary; AJCC staging edition: 8th; Prior malignancy: no; Prior treatment: No; Tumor depth: 8.9 mm.
   Pathology details: Additional pathology findings: Tumor has rough spikey edges; Lymphatic invasion present: Yes; Vascular invasion present: Yes.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis; Days to treatment start: 0 days.
   Recorded as not given: neoadjuvant treatment (type not reported); adjuvant Pharmaceutical Therapy, NOS, for residual disease; adjuvant Radiation Therapy, NOS, for residual disease.

Follow-up (1 entry)
- Days to follow up: 98 days; Disease response: Complete Response; Progression or recurrence: No.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 79 kg; Height: 172 cm; BMI: 26.7.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker.

Family history
- Relationship type: First Degree Relative, NOS.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample HCM-CSHL-0725-C02-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Preservation method: Frozen.
  Slide HCM-CSHL-0725-C02-11A-01-S2-HE: Section location: Bottom; Percent tumor cells: 0; Percent tumor nuclei: 0; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 100; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
  Slide HCM-CSHL-0725-C02-11A-01-S1-HE: Section location: Top; Percent tumor cells: 0; Percent tumor nuclei: 0; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 100; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample HCM-CSHL-0725-C02-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 7.
